Gene-level copy-number profile of tumor specimen TCGA-02-0325-01A from TCGA case TCGA-02-0325, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.9 years (22,598 days).
Specimen TCGA-02-0325-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.61ed88af-5ddc-4505-99d5-5ce87ca0dd7a.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,924 have no estimate.
https://portal.gdc.cancer.gov/files/926dfb57-e3e0-48a6-88bd-d98e7945d96f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 11,628; copy number 2: 41,052; copy number 3: 2,985.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0325-01): tumor purity 0.49, ploidy 1.85, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,128,103, 17 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:22,446,824–22,455,740, 1 gene: DMRTA1.
- chr9:23,671,788–25,089,151, 12 genes: AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:26,642,697–26,805,862, 4 genes: AL442639.1, AL451137.2, AL451137.1, AL356133.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
